FM case AD11158 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/4dad8051-4979-4381-97e8-59ac41725a0a

Male, 38.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the appendix; metastasis biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
